Gene-level copy-number profile of tumor specimen TCGA-BA-6871-01A from TCGA case TCGA-BA-6871, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; Tumor grade: G2; Age at diagnosis: 75.9 years (27,708 days).
Specimen TCGA-BA-6871-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.6c4bd3a1-bb9d-47c7-8981-d6f7813c0abf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-6871-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2e19dfa1-775f-448f-8763-cca3df33ecd1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 933; copy number 2: 29,080; copy number 3: 18,340; copy number 4: 6,089; copy number 5: 2,171; copy number 6: 218; copy number 7: 922; copy number 8: 209; copy number 9: 1,043; copy number 10: 200; copy number 11: 39; copy number 13: 30; copy number 14: 109; copy number 15: 87; copy number 16: 44; copy number 18: 281.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-6871-01A-11D-1869-01): tumor purity 0.7, ploidy 2.95, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,892,188–22,824,213, 13 genes (within-gene range 0–2): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.
- chr11:98,130,239–98,945,079, 4 genes: AP001317.1, AP003038.1, AP003715.1, AP002428.1.
- chr11:99,120,176–99,120,490, 1 gene: RN7SKP53.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,351 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,101,103, 2,561 genes, copy number 5–11 (broad region; genes not listed).
- chr3:134,597,801–198,222,513, 1,094 genes, copy number 6–14 (broad region; genes not listed).
- chr5:92,151–1,386,409, 52 genes, copy number 10–14 (within-gene range 1–14): PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32, AC026748.3.
- chr5:12,297,399–23,329,892, 138 genes, copy number 5–14 (broad region; genes not listed).
- chr8:100,957,883–145,066,685, 679 genes, copy number 5–10 (broad region; genes not listed).
- chr11:68,460,731–72,290,688, 125 genes, copy number 10 (within-gene range 3–10) (broad region; genes not listed).
- chr11:72,302,139–72,302,965, 1 gene, copy number 10: AP000593.3.
- chr12:66,767–12,568,776, 458 genes, copy number 6–18 (broad region; genes not listed).
- chr12:18,080,869–20,688,583, 31 genes, copy number 5 (within-gene range 3–5): RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1, LINC02468, AC129102.1, PDE3A, UBE2L2.
- chr17:27,237,859–29,404,105, 134 genes, copy number 8–15 (broad region; genes not listed).
- chr17:29,390,662–29,445,400, 3 genes, copy number 15: MIR4523, RNU6-711P, RNU6-1034P.
- chr18:706,523–4,455,307, 75 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 810. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
